Somatic mutation profile of tumor specimen TARGET-10-PANTVC-09A (aliquot TARGET-10-PANTVC-09A-01D) from TARGET case TARGET-10-PANTVC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (674 days).
Specimen TARGET-10-PANTVC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49aeacf9-1b6e-45f7-a3c7-6e5f503667f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTVC-14A (Bone Marrow Normal), aliquot TARGET-10-PANTVC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35fb995c-e265-4508-8524-4b15b49a2731

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH18 | c.3179C>T p.T1060M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs531335234, COSV61267224; called by muse, mutect2, varscan2
- TMPRSS7 | c.344G>A p.R115H (on ENST00000452346; = p.R3H on NM_001042575.2) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as rs11914332; called by muse, mutect2, varscan2
- CHD4 | c.1337G>A p.G446E (on ENST00000357008 / NM_001363606.2; = p.G459E on NM_001273.5) | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- RNF103 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TECPR1 | c.227G>C p.R76P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UTP20 | c.3723G>A p.A1241= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as rs755846428; called by muse, mutect2, varscan2
- RNF207 | c.1297-10C>T | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
